FM case AD14468 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/09f062f2-07de-43ad-9c3f-36bc817ac703

Male, 59.7 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); specimen biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 63% (pathologist estimate recorded by GDC). Sample type: Tumor.
